Gene-level copy-number profile of tumor specimen TCGA-FD-A62N-01A from TCGA case TCGA-FD-A62N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,297 days).
Specimen TCGA-FD-A62N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9dbd9bb9-8e84-4aaf-a587-8e468792a443.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A62N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 369 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4e5ec36e-46c0-4a51-b9cd-221101614f8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,890; copy number 1: 24,433; copy number 2: 29,936; copy number 3: 2,179; copy number 4: 11; copy number 5: 731; copy number 6: 5; copy number 7: 60; copy number 8: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A62N-01A-11D-A30D-01): tumor purity 0.25, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 518 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:76,886,029–77,040,384, 5 genes (within-gene range 0–1): AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6.
- chr6:29,925,983–29,929,232, 2 genes: HCG4B, HLA-K.
- chr6:31,519,480–33,418,317, 175 genes (broad region; genes not listed).
- chr7:38,257,879–38,322,730, 10 genes: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr10:88,664,441–89,207,317, 20 genes: LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H.
- chr12:59,812,102–59,812,576, 1 gene: AC079905.1.
- chr13:85,693,937–85,783,203, 1 gene (within-gene range 0–1): AL356413.1.
- chr14:18,333,726–19,976,659, 84 genes (broad region; genes not listed).
- chr14:21,797,287–22,499,749, 85 genes (broad region; genes not listed).
- chr14:23,969,874–24,051,377, 3 genes (within-gene range 0–2): DHRS4L2, AL136419.1, AL136419.3.
- chr16:82,192,505–82,192,790, 1 gene: RN7SKP190.
- chr16:89,215,211–90,096,354, 43 genes: AC009113.1, ZNF778, AC009113.2, ANKRD11, AC137932.3, AC137932.1, AC137932.2, AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7.
- chr17:65,654,914–65,655,395, 1 gene: AC004805.2.
- chr20:55,408,898–58,981,169, 87 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 805 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:99,242,246–99,304,742, 2 genes, copy number 7: LYG2, LYG1.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr5:104,917,492–105,246,364, 2 genes, copy number 5 (within-gene range 2–5): AC091987.1, RAB9BP1.
- chr6:30,839,526–30,900,156, 5 genes, copy number 6: LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640.
- chr8:39,314,591–39,730,065, 4 genes, copy number 5 (within-gene range 1–5): ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr10:58,512,872–59,363,181, 9 genes, copy number 8 (within-gene range 4–8): BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1.
- chr10:66,079,243–66,118,326, 1 gene, copy number 7 (within-gene range 4–7): AC022017.1.
- chr11:92,161,106–92,161,889, 1 gene, copy number 7: RPL7AP57.
- chr11:94,128,841–98,945,079, 64 genes, copy number 5–7 (broad region; genes not listed).
- chr11:99,120,176–99,120,490, 1 gene, copy number 5: RN7SKP53.
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 2–5): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 5: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 23,883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
